Surgical pathology report (de-identified scan), TCGA case TCGA-QH-A6X8, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Fondazione-Besta, specimen TCGA-QH-A6X8-01A (Primary Tumor).

OBJECT: PATHOLOGIST REPORT

Code:

Gender: F

Age:

Date of surgery:

Localization: L frontal

Diagnosis: Anaplastic oligodendroglioma (grade III WHO)

Name of Pathologist:

ICD-O-3
Oligodendroglioma, grade III
945/13
Site: Brain, supratentorial NOS
C71.0
QW8/12/13

Source: NCI Genomic Data Commons file b880fd7d-c7ae-46dc-aa7b-fee29884b333 (TCGA-QH-A6X8.01982953-8F6F-4BDE-B645-824E04C6CAAB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).